Somatic mutation profile of tumor specimen C3N-00340-03 (aliquot CPT0022620006) from CPTAC case C3N-00340, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.7 years (22,158 days).
Specimen C3N-00340-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f942c88e-1deb-45a9-b934-b3bd5d6f795d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00340-31 (Blood Derived Normal), aliquot CPT0020710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61564127-813f-4d7e-9c75-e96091c9624d

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 9, Intron 4, Splice Site 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.1696+1G>T p.X566_splice | Splice Site (SNP) | VAF 33/316 reads (10%) | catalogued as rs954701825, COSV61636467; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 81/198 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANKFN1 | c.3716G>A p.R1239H (on ENST00000653862; = p.R1092H on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/326 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs1175578758, COSV73719026; called by muse, mutect2, varscan2
- CRYGD | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 110/367 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165341253; called by muse, mutect2, varscan2
- DCAF4L2 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs768543194, COSV60477231; called by muse, mutect2, varscan2
- DIDO1 | c.6212G>A p.R2071Q | Missense Mutation (SNP) | VAF 76/357 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1261253654; called by muse, mutect2, varscan2
- GOLGB1 | c.9448G>A p.V3150M | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs547521254; called by muse, mutect2, varscan2
- MAP1A | c.7334G>A p.R2445H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs780155123; called by muse, mutect2, varscan2
- MLXIPL | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs782671517, COSV57670951; called by muse, varscan2
- MYCBP2 | c.11941A>G p.M3981V (on ENST00000357337; = p.M4019V on NM_015057.5) | Missense Mutation (SNP) | VAF 104/375 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV62010170; called by muse, mutect2, varscan2
- NRXN1 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58473886; called by muse, mutect2
- SLC20A2 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs896549052; called by muse, mutect2, varscan2
- TRIP11 | c.2069G>C p.R690T | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV99971194; called by muse, mutect2
- TRPM5 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs781201725, COSV50195465; called by muse, mutect2, varscan2
- USP22 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV54946032; called by muse, mutect2, varscan2
- VWA8 | c.1990C>T p.R664* | Nonsense Mutation (SNP) | VAF 23/206 reads (11%) | catalogued as rs757480126, COSV55697371; called by muse, mutect2, varscan2
- XPOT | c.2333G>C p.R778P | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV100225303; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV54298314, COSV99648331; called by muse, mutect2, varscan2
- AGL | c.4556C>G p.A1519G | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP20 | c.1880A>T p.Q627L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ASB12 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- CDK11B | c.1976A>T p.E659V | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- CPNE5 | c.1112A>C p.Q371P | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LYSMD2 | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MEGF8 | c.3294del p.Y1098* (on ENST00000251268 / NM_001271938.2; = p.Y1031* on NM_001410.3) | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- NOBOX | c.292+1G>A p.X98_splice | Splice Site (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2
- PKP4 | c.1695G>T p.E565D | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- PRKAA2 | c.992G>T p.R331L | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- RGS7 | c.582A>T p.R194S | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SALL3 | c.3255G>T p.Q1085H | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHISA6 | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2
- SYNPO2 | c.2612G>C p.R871T | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TNRC6B | c.490T>G p.Y164D | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TRAV9-1 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2
- ULBP2 | c.456C>A p.D152E | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- ZNF407 | c.3548T>A p.M1183K | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF536 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRS2 | c.3330C>G p.L1110= | Silent (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- KRT37 | c.837G>A p.Q279= | Silent (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- PCDHB16 | c.2130G>A p.A710= | Silent (SNP) | VAF 74/396 reads (19%) | catalogued as rs549792075, COSV99501612; called by muse, mutect2, varscan2
- RNF213 | c.3609G>A p.S1203= | Silent (SNP) | VAF 99/290 reads (34%) | catalogued as rs943130448, COSV71705519; called by muse, mutect2, varscan2
- SFMBT2 | c.2421G>A p.T807= | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as rs769325050, COSV62818193; called by muse, mutect2, varscan2
- SLC6A17 | c.1878C>T p.V626= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs367697353; called by muse, mutect2, varscan2
- USP17L7 | c.993C>T p.H331= | Silent (SNP) | VAF 69/648 reads (11%) | called by muse, mutect2, varscan2
- WDR97 | c.438G>T p.A146= | Silent (SNP) | VAF 61/224 reads (27%) | catalogued as rs1468315476; called by muse, mutect2, varscan2
- ZNF556 | c.1239C>G p.S413= | Silent (SNP) | VAF 29/197 reads (15%) | called by muse, mutect2, varscan2
- CCDC74A | c.251-50G>T | Intron (SNP) | VAF 33/297 reads (11%) | called by muse, mutect2, varscan2
- KAT6B | c.1993+46_1993+59del | Intron (DEL) | VAF 28/266 reads (11%) | called by mutect2, pindel
- TOX2 | c.907-863G>A | Intron (SNP) | VAF 30/130 reads (23%) | catalogued as rs142800786; called by muse, mutect2, varscan2
- TRIP10 | c.*62_*63dup | 3'UTR (INS) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- TTC23 | c.1144-69G>T | Intron (SNP) | VAF 28/171 reads (16%) | called by muse, mutect2, varscan2
